Somatic mutation profile of tumor specimen TARGET-10-PANXXD-09A (aliquot TARGET-10-PANXXD-09A-01D) from TARGET case TARGET-10-PANXXD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,362 days).
Specimen TARGET-10-PANXXD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ecc020f-69d1-41c2-ad6b-73311bf1be42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANXXD-14A (Bone Marrow Normal), aliquot TARGET-10-PANXXD-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55785c4f-4c37-4524-8361-e4dfabee006b

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 1, Splice Site 1, Intron 1, In Frame Del 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL3 | c.843C>A p.Y281* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as rs891002312; called by muse, mutect2, varscan2
- CAPS2 | c.1465G>T p.A489S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV60824076; called by muse, mutect2
- CLK1 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV58436594; called by muse, mutect2, varscan2
- SCN11A | c.1546C>G p.P516A | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV56568980; called by muse, mutect2, varscan2
- TAAR6 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs202204870, COSV51584698, COSV99256587; called by muse, mutect2, varscan2
- TENM4 | c.2573G>T p.C858F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53615426; called by muse, mutect2
- TRIM39 | c.757C>A p.Q253K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV64955351; called by muse, mutect2, varscan2
- ZMYM6 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as rs772780362, COSV64121869; called by muse, mutect2, varscan2
- ZNF77 | c.691G>T p.V231L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs1307920121; called by muse, mutect2
- ACOT7 | c.32G>T p.C11F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.005); called by muse, varscan2
- ATRX | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.321); called by muse, mutect2
- HDLBP | c.1189G>T p.V397F | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- HJURP | c.1801G>T p.V601L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2
- HYDIN | c.4558G>A p.D1520N | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- IGHV3-53 | c.347_348insCTCCGAG p.R116Sfs*? | Frame Shift Ins (INS) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- MROH2A | c.3653C>A p.A1218D | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- SACS | c.5504G>T p.S1835I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by mutect2, varscan2
- SCN11A | c.1767C>G p.I589M | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- SCN9A | c.5815G>C p.E1939Q (on ENST00000303354; = p.E1928Q on NM_002977.3) | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.31); called by muse, varscan2
- SERAC1 | c.1167-1G>T p.X389_splice | Splice Site (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- SPATA13 | c.517_519del p.V173del | In Frame Del (DEL) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- VCP | c.2368G>T p.G790C | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.366); called by muse, mutect2
- HDGFL1 | c.246C>T p.I82= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV57752809; called by muse, mutect2, varscan2
- MBOAT1 | c.723G>T p.V241= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- NLRP12 | c.2277C>T p.C759= | Silent (SNP) | VAF 38/97 reads (39%) | catalogued as rs763712459, COSV60744776; called by muse, mutect2, varscan2
- WDR64 | c.1764C>A p.L588= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV63801127; called by muse, varscan2
- DAGLB | c.1141-206G>T | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- EXOSC5 | c.-1G>T | 5'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
